Somatic mutation profile of tumor specimen TCGA-Q2-A5QZ-01A (aliquot TCGA-Q2-A5QZ-01A-11D-A28G-10) from TCGA case TCGA-Q2-A5QZ, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 61.7 years (22,531 days).
Specimen TCGA-Q2-A5QZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f3369cdd-0ce6-4d92-b139-2b62406b9c1f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-Q2-A5QZ-10A (Blood Derived Normal), aliquot TCGA-Q2-A5QZ-10A-01D-A28G-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eda7047b-587b-4937-b65f-1a69235dd04d

The open-access MAF lists 75 somatic variants for this specimen: 59 protein-altering or splice-affecting, 16 silent.
By variant classification: Missense Mutation 45, Silent 16, Frame Shift Del 7, Splice Site 3, Nonsense Mutation 2, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RHEB | c.103T>A p.Y35N | Missense Mutation (SNP) | VAF 5/90 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519949, COSV51263142, COSV51264088; ClinVar: likely pathogenic; called by muse, mutect2
- ADAM18 | c.1902+2T>A p.X634_splice | Splice Site (SNP) | VAF 58/171 reads (34%) | catalogued as COSV55856105; called by muse, mutect2, varscan2
- AGAP3 | c.1726G>A p.V576M (on ENST00000622464; = p.V612M on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 114/302 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68246973; called by muse, mutect2, varscan2
- ARFGAP1 | c.930T>G p.S310R | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as COSV62264096; called by muse, mutect2, varscan2
- ARHGEF40 | c.1525G>C p.D509H | Missense Mutation (SNP) | VAF 57/210 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV53884756; called by muse, mutect2, varscan2
- BRWD3 | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 92/287 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as rs752898370, COSV64754052; called by muse, mutect2, varscan2
- CD2AP | c.104A>T p.E35V | Missense Mutation (SNP) | VAF 28/382 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV63760130, COSV63763292; called by muse, mutect2
- CLCA1 | c.52G>A p.G18R | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.995); catalogued as rs377703691; called by muse, mutect2, varscan2
- CUL2 | c.49C>G p.L17V | Missense Mutation (SNP) | VAF 39/161 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs1157873336, COSV66081374; called by muse, mutect2, varscan2
- DDN | c.982G>A p.G328S | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.125); catalogued as COSV60294964; called by muse, mutect2, varscan2
- DGKG | c.1795A>T p.R599* | Nonsense Mutation (SNP) | VAF 30/105 reads (29%) | catalogued as COSV53973614; called by muse, mutect2, varscan2
- ENTR1 | c.401A>C p.K134T (on ENST00000357365 / NM_001039707.2; = p.K111T on NM_006643.4) | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.957); catalogued as COSV53743491; called by muse, mutect2, varscan2
- FARP1 | c.2516+2T>A p.X839_splice | Splice Site (SNP) | VAF 13/67 reads (19%) | catalogued as COSV60349361; called by muse, mutect2, varscan2
- FRMPD1 | c.3116G>A p.G1039E | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.012); catalogued as COSV66703477; called by muse, mutect2, varscan2
- HDAC5 | c.178C>T p.R60W | Missense Mutation (SNP) | VAF 70/149 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.924); catalogued as rs772611618, COSV56821579; called by muse, mutect2, varscan2
- HDC | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 58/146 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0.307); catalogued as COSV51068258; called by muse, mutect2, varscan2
- HINFP | c.194C>G p.S65C | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV63432806; called by muse, varscan2
- IBTK | c.3742A>G p.T1248A | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV60396508; called by muse, mutect2
- KLRK1 | c.127A>G p.K43E | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV53700001; called by muse, mutect2, varscan2
- KMT2A | c.7316A>C p.E2439A | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.162); catalogued as COSV63293123; called by muse, mutect2, varscan2
- KNL1 | c.2926G>T p.V976F (on ENST00000346991 / NM_170589.5; = p.V950F on NM_144508.5) | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV61160817; called by muse, mutect2, varscan2
- LYZL6 | c.364G>C p.G122R | Missense Mutation (SNP) | VAF 56/105 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs778612712; called by muse, mutect2, varscan2
- MUC2 | c.626C>T p.P209L | Missense Mutation (SNP) | VAF 58/206 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs1252124891; called by muse, mutect2, varscan2
- NFASC | c.3610G>T p.E1204* (on ENST00000339876 / NM_001378329.1; = p.E1133* on NM_015090.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 31/291 reads (11%) | catalogued as COSV58381698; called by muse, mutect2, varscan2
- NIPSNAP3A | c.741A>C p.K247N | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV66106990; called by muse, mutect2, varscan2
- NRXN1 | c.904C>A p.Q302K | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.425); catalogued as COSV58497247; called by muse, mutect2, varscan2
- OR4X1 | c.190T>G p.L64V | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as COSV60722791; called by muse, mutect2, varscan2
- OR7E24 | c.462G>C p.M154I | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV71702232, COSV71702374; called by muse, mutect2, varscan2
- PDZD7 | c.380T>C p.L127P | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64647732; called by muse, mutect2, varscan2
- PHF3 | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 87/220 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV50345138; called by muse, mutect2, varscan2
- PHKA2 | c.2972G>T p.G991V | Missense Mutation (SNP) | VAF 60/174 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV66056617; called by muse, mutect2, varscan2
- PPP2R2C | c.884A>G p.Y295C | Missense Mutation (SNP) | VAF 70/116 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV59448085; called by muse, mutect2, varscan2
- PRPS2 | c.885C>G p.I295M | Missense Mutation (SNP) | VAF 65/217 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.204); catalogued as COSV66180344; called by muse, mutect2, varscan2
- PRRT2 | c.979A>C p.I327L | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54886914; called by muse, mutect2, varscan2
- PTCHD4 | c.284A>G p.D95G | Missense Mutation (SNP) | VAF 20/364 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.438); catalogued as rs1355395173, COSV59798500; called by muse, mutect2
- PTPRG | c.1621G>C p.A541P | Missense Mutation (SNP) | VAF 60/90 reads (67%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.462); catalogued as COSV55630513, COSV55644504, COSV55664419; called by muse, mutect2, varscan2
- PTPRO | c.1843G>A p.D615N | Missense Mutation (SNP) | VAF 72/240 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.245); catalogued as COSV55503916, COSV99841609; called by muse, mutect2, varscan2
- ROPN1B | c.13G>T p.D5Y | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52543393; called by muse, mutect2, varscan2
- SCN9A | c.5329G>A p.D1777N (on ENST00000303354; = p.D1766N on NM_002977.3) | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57626268; called by muse, mutect2
- SCNN1A | c.1985C>T p.S662F | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.046); catalogued as COSV57437523; called by muse, mutect2, varscan2
- SH3BGRL | c.70C>A p.L24I | Missense Mutation (SNP) | VAF 73/227 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.774); catalogued as COSV64623031; called by muse, varscan2
- SOST | c.166A>G p.M56V | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.041); catalogued as COSV57013371; called by muse, mutect2, varscan2
- SPOPL | c.935A>G p.H312R | Missense Mutation (SNP) | VAF 25/161 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV54516753; called by muse, mutect2, varscan2
- SVEP1 | c.2902G>T p.A968S | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT tolerated (0.74); PolyPhen benign (0.012); catalogued as COSV57049017; called by muse, mutect2, varscan2
- TET1 | c.2407G>T p.A803S | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.264); catalogued as COSV65383974, COSV65389936; called by muse, mutect2, varscan2
- TGM7 | c.202C>A p.P68T | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71773163, COSV71773196; called by muse, mutect2, varscan2
- TRA2A | c.607C>T p.P203S | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV51719210; called by muse, mutect2, varscan2
- TTC25 | c.1488A>T p.K496N | Missense Mutation (SNP) | VAF 55/135 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as COSV66369295; called by muse, mutect2, varscan2
- ZNF451 | c.311G>A p.R104K | Missense Mutation (SNP) | VAF 16/254 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV62600219; called by muse, mutect2
- ADGRG4 | c.8078_8079insAAATA p.N2693Kfs*16 | Frame Shift Ins (INS) | VAF 14/57 reads (25%) | called by mutect2, pindel, varscan2
- B9D2 | c.33del p.I11Mfs*41 | Frame Shift Del (DEL) | VAF 59/129 reads (46%) | called by mutect2, pindel, varscan2
- BRINP2 | c.727_736del p.V243Sfs*28 | Frame Shift Del (DEL) | VAF 32/180 reads (18%) | called by mutect2, pindel, varscan2
- CIZ1 | c.549del p.K183Nfs*80 | Frame Shift Del (DEL) | VAF 30/113 reads (27%) | called by mutect2, pindel, varscan2
- CUX2 | c.4092dup p.Q1365Tfs*4 | Frame Shift Ins (INS) | VAF 22/69 reads (32%) | called by mutect2, pindel, varscan2
- GABRQ | c.201_202del p.S68Kfs*27 | Frame Shift Del (DEL) | VAF 50/165 reads (30%) | called by mutect2, pindel, varscan2
- KMT2C | c.427del p.S143Vfs*3 | Frame Shift Del (DEL) | VAF 45/141 reads (32%) | called by mutect2, pindel, varscan2
- PKHD1 | c.4422del p.N1475Ifs*6 | Frame Shift Del (DEL) | VAF 45/225 reads (20%) | called by mutect2, pindel, varscan2
- TCP11L2 | c.961-8_963del p.X321_splice | Splice Site (DEL) | VAF 7/25 reads (28%) | called by mutect2, pindel, varscan2
- ZFHX3 | c.3288del p.T1097Pfs*14 | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | called by mutect2, varscan2
- BRI3BP | c.420C>A p.S140= | Silent (SNP) | VAF 31/81 reads (38%) | catalogued as COSV58297542; called by muse, mutect2, varscan2
- CIPC | c.777C>T p.F259= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as rs773721062, COSV62377402; called by muse, mutect2, varscan2
- CSPG4 | c.540C>G p.L180= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as COSV57902219; called by muse, mutect2, varscan2
- EEF1AKMT1 | c.369A>G p.P123= | Silent (SNP) | VAF 34/77 reads (44%) | catalogued as COSV66965360; called by muse, mutect2, varscan2
- GIGYF2 | c.1800T>A p.P600= | Silent (SNP) | VAF 34/52 reads (65%) | catalogued as COSV65253832; called by muse, mutect2, varscan2
- HMOX2 | c.468C>T p.R156= | Silent (SNP) | VAF 80/202 reads (40%) | catalogued as COSV54861931; called by muse, mutect2, varscan2
- IQCA1 | c.1752G>A p.L584= | Silent (SNP) | VAF 94/180 reads (52%) | catalogued as rs1345374258, COSV54507272, COSV54513839; called by muse, mutect2, varscan2
- OPN1SW | c.414G>A p.K138= | Silent (SNP) | VAF 54/196 reads (28%) | catalogued as COSV50823624; called by muse, mutect2
- OTULINL | c.279G>A p.E93= | Silent (SNP) | VAF 44/187 reads (24%) | catalogued as COSV57036767; called by muse, varscan2
- PPP2R3A | c.3273T>C p.A1091= | Silent (SNP) | VAF 35/112 reads (31%) | catalogued as COSV53871467; called by muse, mutect2, varscan2
- PRKACG | c.714C>T p.P238= | Silent (SNP) | VAF 32/88 reads (36%) | catalogued as COSV55258755; called by muse, mutect2, varscan2
- RAD9B | c.1248A>G p.K416= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV62827423; called by muse, mutect2, varscan2
- RBM19 | c.1341C>T p.F447= | Silent (SNP) | VAF 59/260 reads (23%) | catalogued as COSV55699046; called by muse, mutect2, varscan2
- SLC43A3 | c.999C>T p.P333= | Silent (SNP) | VAF 57/169 reads (34%) | catalogued as rs1161172783, COSV61451445; called by muse, mutect2, varscan2
- TGM7 | c.201G>A p.K67= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as COSV71773197; called by muse, mutect2, varscan2
- ZNF571 | c.1293C>T p.G431= | Silent (SNP) | VAF 19/31 reads (61%) | catalogued as COSV100144059; called by muse, mutect2, varscan2
